Gene-level copy-number profile of tumor specimen TCGA-A6-2677-01B from TCGA case TCGA-A6-2677, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.8 years (25,143 days).
Specimen TCGA-A6-2677-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.4be79593-92db-49f6-810c-2f4c6fb4d1b5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-2677-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate.
https://portal.gdc.cancer.gov/files/9ed2cdf3-7219-4d66-92f7-cadcff00d35e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 573; copy number 2: 59,308; copy number 3: 295; copy number 4: 22; copy number 5: 47; copy number 6: 2; copy number 7: 17; copy number 13: 1; copy number 14: 1; copy number 30: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-2677-01A-01D-A274-01): tumor purity 0.88, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:36,575,574–36,598,279, 1 gene (within-gene range 0–2): RAG2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 69 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:98,660,388–98,661,059, 1 gene, copy number 5: AC095031.1.
- chr1:152,759,561–152,762,052, 1 gene, copy number 6: KPRP.
- chr3:121,099,108–121,099,774, 1 gene, copy number 7: AC078857.1.
- chr3:124,965,710–125,055,997, 1 gene, copy number 5 (within-gene range 1–5): HEG1.
- chr3:130,089,433–130,094,304, 1 gene, copy number 30: LINC02014.
- chr6:5,997,999–6,007,605, 1 gene, copy number 7: NRN1.
- chr6:27,679,971–27,680,555, 1 gene, copy number 7: AL009179.2.
- chr10:93,893,973–93,956,062, 1 gene, copy number 6 (within-gene range 2–6): SLC35G1.
- chr13:48,316,863–48,320,475, 1 gene, copy number 14: PPP1R26P1.
- chr14:70,906,657–70,907,111, 1 gene, copy number 13: AC004825.2.
- chr15:25,054,210–25,081,378, 14 genes, copy number 7: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.
- chr15:25,172,635–25,250,940, 43 genes, copy number 5: SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr20:45,435,272–45,481,532, 2 genes, copy number 5 (within-gene range 2–5): AL031663.3, WFDC2.

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
